Somatic mutation profile of tumor specimen TCGA-HM-A3JJ-01A (aliquot TCGA-HM-A3JJ-01A-21D-A21Q-09) from TCGA case TCGA-HM-A3JJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 40.3 years (14,736 days).
Specimen TCGA-HM-A3JJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ade39961-c5d4-41f2-a6f6-3d49c55bd0f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HM-A3JJ-10A (Blood Derived Normal), aliquot TCGA-HM-A3JJ-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d62b67f-ad74-487e-a189-4741bc1ad9d9

The open-access MAF lists 61 somatic variants for this specimen: 49 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 11, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.670C>T p.R224* (on ENST00000281708 / NM_001349798.2; = p.R144* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | hotspot (GDC flag); catalogued as rs1406877044, COSV55899023; called by muse, mutect2, varscan2
- ABCA13 | c.10935C>A p.S3645R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101447207; called by muse, mutect2, varscan2
- ANKRD27 | c.2563C>T p.H855Y | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.694); catalogued as COSV100043151; called by muse, mutect2, varscan2
- BMS1 | c.2792G>A p.W931* | Nonsense Mutation (SNP) | VAF 31/168 reads (18%) | catalogued as COSV100996822; called by muse, mutect2, varscan2
- CEP72 | c.1590A>C p.L530F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99375280; called by muse, mutect2, varscan2
- CHRM2 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.491); catalogued as COSV100281910; called by muse, mutect2, varscan2
- COL1A2 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317653638, COSV99801057; called by muse, mutect2, varscan2
- DCAF12L1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64421454; called by muse, mutect2, varscan2
- DMD | c.4053G>C p.W1351C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs1454477626, COSV100822694; called by muse, mutect2, varscan2
- ELP1 | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101010490; called by muse, mutect2, varscan2
- ENDOV | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV100108433; called by muse, mutect2, varscan2
- FAM47A | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs878906003; called by muse, mutect2, varscan2
- FTL | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as rs559631027, COSV53170348, COSV99509248; called by muse, mutect2, varscan2
- GPR22 | c.177C>A p.N59K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99773156; called by muse, mutect2, varscan2
- H2AC21 | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100480168; called by muse, mutect2, varscan2
- H3-4 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.885); catalogued as rs369460992, COSV64210573; called by muse, mutect2, varscan2
- IRX6 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750729036, COSV51861788, COSV99306447; called by muse, mutect2, varscan2
- KHDRBS2 | c.847C>A p.Q283K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV99837433; called by muse, varscan2
- KRT35 | c.513G>C p.E171D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99877913; called by muse, mutect2, varscan2
- MAGEB10 | c.58G>C p.G20R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.558); catalogued as COSV100775396; called by muse, mutect2, varscan2
- MAP3K6 | c.2857C>A p.Q953K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.931); catalogued as COSV58870036, COSV58874217; called by muse, mutect2, varscan2
- NDST2 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100013526, COSV100014362; called by muse, mutect2, varscan2
- NPAS2 | c.1686G>T p.E562D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100176940; called by muse, mutect2, varscan2
- OR10W1 | c.336C>A p.D112E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67720846; called by muse, varscan2
- OR56B4 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.192); catalogued as COSV100337617; called by muse, mutect2, varscan2
- PHKA2 | c.2649G>T p.Q883H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV101177444; called by muse, mutect2, varscan2
- PLCH1 | c.197T>C p.I66T (on ENST00000340059 / NM_001130960.2; = p.I78T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs376738258; called by muse, mutect2
- PPP2R2D | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV70778958; called by muse, mutect2, varscan2
- PRKCA | c.1663G>A p.V555I | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as rs1041174047, COSV101151263; called by muse, mutect2, varscan2
- PXDNL | c.3808G>A p.D1270N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.735); catalogued as COSV100686242; called by muse, mutect2, varscan2
- RAD54B | c.2089T>C p.S697P | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); catalogued as COSV100280178; called by muse, mutect2, varscan2
- SGSM2 | c.2980G>A p.D994N (on ENST00000426855 / NM_001098509.2; = p.D1039N on NM_014853.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV99280550; called by muse, mutect2, varscan2
- SH2D3C | c.32A>T p.K11M | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100137536; called by muse, mutect2, varscan2
- TAF1 | c.4058C>T p.S1353F (on ENST00000373790 / NM_138923.4; = p.S1374F on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.285); catalogued as COSV52128973, COSV99336960; called by muse, mutect2, varscan2
- TASOR | c.2347C>T p.R783C (on ENST00000355628 / NM_001365636.2; = p.R387C on NM_015224.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.747); catalogued as rs370672814; called by muse, mutect2, varscan2
- TG | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV99603118; called by muse, mutect2
- TMCO6 | c.1050C>A p.F350L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99347399; called by muse, mutect2, varscan2
- TSHZ1 | c.1973C>T p.P658L (on ENST00000580243 / NM_001308210.2; = p.P613L on NM_005786.6) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs769798292, COSV59006033; called by muse, mutect2
- TTN | c.83845G>C p.E27949Q (on ENST00000591111; = p.E20525Q on NM_003319.4) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | PolyPhen possibly damaging (0.544); catalogued as rs72648236, COSV100629354; called by muse, mutect2, varscan2
- UBR4 | c.11581G>A p.V3861I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.796); catalogued as rs374622336; called by mutect2, varscan2
- WARS1 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs751453486, COSV100690340; called by muse, mutect2, varscan2
- ZFP14 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.341); catalogued as rs768243359, COSV54203612; called by muse, mutect2, varscan2
- ZNF182 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.51); catalogued as rs782476080, COSV100527209; called by muse, mutect2, varscan2
- ZNF208 | c.2002A>G p.K668E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs879149580, COSV68108905; called by muse, mutect2
- ZNF616 | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs770232584, COSV57511313; called by mutect2, varscan2
- DBX1 | c.576del p.Q192Hfs*29 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel
- KNSTRN | c.822+2dup p.X274_splice | Splice Site (INS) | VAF 3/20 reads (15%) | called by mutect2, pindel
- MORF4L1 | c.1003_1004del p.K335Vfs*16 (on ENST00000331268 / NM_206839.2; = p.K296Vfs*16 on NM_006791.4) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- PDE1A | c.1142_1160del p.T381Sfs*12 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, varscan2
- APBA3 | c.894C>T p.A298= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs937204747, COSV99516459; called by muse, mutect2
- CDC42EP4 | c.795G>A p.Q265= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100231988; called by muse, mutect2, varscan2
- CELSR2 | c.7038G>A p.E2346= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99604698; called by muse, mutect2, varscan2
- DSG1 | c.2733C>T p.I911= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs1354966914, COSV99936555; called by muse, mutect2, varscan2
- EHD3 | c.336C>T p.N112= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs146965464; called by mutect2, varscan2
- KLHL13 | c.1641A>C p.G547= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV99452495; called by muse, mutect2, varscan2
- LCT | c.4086C>T p.N1362= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as rs202245718, COSV99929469; called by muse, mutect2
- MSTO1 | c.729G>A p.A243= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs756235713, COSV55471659; called by muse, mutect2
- MYF5 | c.204C>T p.L68= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99953398; called by muse, mutect2
- RIPOR3 | c.2250C>T p.P750= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs758166271, COSV50386059, COSV99247153; called by muse, mutect2, varscan2
- VCAN | c.1395C>T p.G465= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs772684866, COSV54102683; called by muse, mutect2, varscan2
- ZNF419 | c.298+22G>A | Intron (SNP) | VAF 16/112 reads (14%) | catalogued as COSV99692604; called by muse, mutect2, varscan2
